Somatic mutation profile of tumor specimen 0DLBMT from CCDI case PBBZGH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.0 years (5,852 days).
Specimen 0DLBMT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b85bfa59-2c51-45b7-a074-37b3effb920c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLBM1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbcd61de-7b14-4cde-b2bd-612bf2aa7ba1

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Intron 2, 5'UTR 2, In Frame Ins 1, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 194/493 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 99/459 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1H | c.3338C>T p.P1113L | Missense Mutation (SNP) | VAF 222/482 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.838); catalogued as rs753159318, COSV100673773; called by muse, mutect2, varscan2
- COL25A1 | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 151/340 reads (44%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.97); catalogued as rs760035323; called by muse, mutect2, varscan2
- DONSON | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 102/251 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); catalogued as rs746846902; called by muse, mutect2, varscan2
- EGFR | c.2311_2313dup p.N771dup | In Frame Ins (INS) | VAF 171/423 reads (40%) | catalogued as COSV51766549, COSV51779915, COSV51787954, COSV51807227, COSV51814184, COSV51816337, COSV51859791; called by mutect2, pindel, varscan2
- EMP2 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs761595098; called by muse, mutect2, varscan2
- FREM2 | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 367/833 reads (44%) | catalogued as COSV99751628; called by muse, mutect2, varscan2
- HCFC1 | c.3731G>A p.R1244H | Missense Mutation (SNP) | VAF 179/386 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs782013532; called by muse, mutect2, varscan2
- HDAC6 | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 187/466 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs147989097, COSV61929547; called by muse, mutect2, varscan2
- ITM2B | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1240049289; called by muse, mutect2, varscan2
- NCBP3 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 137/353 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1190288835, COSV50107116; called by muse, mutect2, varscan2
- PHACTR4 | c.199C>T p.R67W (on ENST00000373839 / NM_001350159.2; = p.R77W on NM_023923.4) | Missense Mutation (SNP) | VAF 229/424 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759224347, COSV65784834; called by muse, mutect2, varscan2
- RIMBP2 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 198/356 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs540874969, COSV55465891; called by muse, mutect2, varscan2
- SETD3 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs753673588; called by muse, mutect2, varscan2
- ZBTB20 | c.1775A>G p.N592S (on ENST00000474710 / NM_001164342.2; = p.N519S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 193/231 reads (84%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs1240860015; called by muse, mutect2, varscan2
- AOC3 | c.106A>G p.S36G | Missense Mutation (SNP) | VAF 203/469 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASPSCR1 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 22/426 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- C19orf67 | c.934C>G p.Q312E | Missense Mutation (SNP) | VAF 107/285 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- CUX2 | c.2368G>A p.A790T | Missense Mutation (SNP) | VAF 195/306 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- FAM47A | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 394/956 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- HEATR5B | c.4009G>C p.V1337L | Missense Mutation (SNP) | VAF 227/557 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HHAT | c.1445T>C p.V482A | Missense Mutation (SNP) | VAF 140/667 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- MCMDC2 | c.610del p.Q204Kfs*2 | Frame Shift Del (DEL) | VAF 102/316 reads (32%) | called by mutect2, pindel, varscan2
- MUC2 | c.1576+1G>A p.X526_splice | Splice Site (SNP) | VAF 77/554 reads (14%) | called by muse, mutect2, varscan2
- PFKP | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYTL2 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 118/316 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCDC17 | c.469C>A p.R157= | Silent (SNP) | VAF 146/526 reads (28%) | catalogued as COSV51974542; called by muse, mutect2, varscan2
- CLCNKB | c.1776C>T p.G592= | Silent (SNP) | VAF 167/623 reads (27%) | called by muse, mutect2, varscan2
- MUC12 | c.8811C>T p.L2937= (on ENST00000379442; = p.L2794= on NM_001164462.1) | Silent (SNP) | VAF 129/2403 reads (5%) | catalogued as rs1202906738; called by muse, mutect2
- MUC16 | c.36300C>T p.N12100= | Silent (SNP) | VAF 36/220 reads (16%) | catalogued as rs370710119; called by muse, mutect2, varscan2
- NAA30 | c.939A>C p.G313= | Silent (SNP) | VAF 42/170 reads (25%) | called by muse, mutect2, varscan2
- DCAF5 | c.395+13G>A | Intron (SNP) | VAF 146/265 reads (55%) | called by muse, mutect2, varscan2
- FARP1 | c.*22G>A | 3'UTR (SNP) | VAF 60/154 reads (39%) | catalogued as rs778819510; called by muse, mutect2, varscan2
- NRG1 | c.1269-400G>T | Intron (SNP) | VAF 33/848 reads (4%) | called by muse, mutect2
- STAG2 | c.-2A>G | 5'UTR (SNP) | VAF 50/305 reads (16%) | called by muse, mutect2, varscan2
- ZNF182 | c.-50A>G | 5'UTR (SNP) | VAF 61/558 reads (11%) | catalogued as rs570131334; called by muse, mutect2, varscan2
